MMRF case MMRF_1972 — Multiple Myeloma CoMMpass Study (MMRF-COMMPASS)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Plasma Cell Tumors; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): first treatment.
https://portal.gdc.cancer.gov/cases/2d4eff51-ba20-4a3d-8628-f64fea7c5c99

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Age at index: 82 years; Vital status: Alive.

Diagnoses (1)
1. Multiple myeloma: ICD-O-3 morphology code: 9732/3; Tissue or organ of origin: Bone marrow; Site of resection or biopsy: Bone marrow; Age at diagnosis: 82.1 years (29,977 days); ISS stage: II; Days to last known disease status: 1,054 days (2.9 years); Days to last follow up: 1,054 days (2.9 years).
   Treatment given: Therapeutic agents: Bortezomib + Cyclophosphamide + Dexamethasone; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 88 days.
   Treatment given: Therapeutic agents: Bortezomib + Cyclophosphamide + Dexamethasone; Regimen or line of therapy: First line of therapy; Days to treatment start: 95 days; Days to treatment end: 368 days (1.0 years).
   Treatment given: Therapeutic agents: Dexamethasone + Lenalidomide; Regimen or line of therapy: Second line of therapy; Days to treatment start: 1,054 days (2.9 years).

Follow-up (1 entry)
- Follow-up contact recording only the day: day 1,054.

Molecular and laboratory tests (laboratory values one line per visit day; values rounded to 3 significant figures where GDC's unit conversion carried more)
- Day -5 (ECOG 0): M Protein 3.1 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 28.5 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.75 mg/dL; Immunoglobulin G 42.1 g/L; Immunoglobulin A 0.1 g/L; Immunoglobulin M 0.16 g/L; Beta 2 Microglobulin 3 µg/mL; Lactate Dehydrogenase 2.17 µkat/L; Hemoglobin 7.63 mmol/L; Leukocytes 3.54 ×10⁹/L; Absolute Neutrophil 1.21 ×10⁹/L; Platelets 172 ×10⁹/L; Creatinine 106 µmol/L; Calcium 2.28 mmol/L; Albumin 32 g/L; Total Protein 8.1 g/dL; Glucose 4.2 mmol/L; C-Reactive Protein 0.09 mg/dL.
- Day 95 (ECOG 1): M Protein 5 g/dL; Beta 2 Microglobulin 3.4 µg/mL; Lactate Dehydrogenase 2.63 µkat/L; Hemoglobin 7.56 mmol/L; Leukocytes 3.18 ×10⁹/L; Absolute Neutrophil 1.94 ×10⁹/L; Platelets 151 ×10⁹/L; Creatinine 106 µmol/L; Calcium 2.23 mmol/L; Albumin 35 g/L; Total Protein 5.3 g/dL; Glucose 5.1 mmol/L.
- Day 179 (ECOG 2): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.24 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.3 mg/dL; Immunoglobulin G 5.06 g/L; Immunoglobulin A 0.07 g/L; Immunoglobulin M 0.08 g/L; Lactate Dehydrogenase 2.43 µkat/L; Hemoglobin 7.56 mmol/L; Leukocytes 5.2 ×10⁹/L; Absolute Neutrophil 3.8 ×10⁹/L; Platelets 230 ×10⁹/L; Creatinine 113 µmol/L; Calcium 2.33 mmol/L; Albumin 36 g/L; Total Protein 5.1 g/dL; Glucose 5.2 mmol/L.
- Day 256 (ECOG 2): M Protein 2 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.3 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.24 mg/dL; Immunoglobulin G 4.09 g/L; Immunoglobulin A 0.1 g/L; Immunoglobulin M 0.26 g/L; Lactate Dehydrogenase 2.43 µkat/L; Hemoglobin 7.63 mmol/L; Leukocytes 3.25 ×10⁹/L; Absolute Neutrophil 1.81 ×10⁹/L; Platelets 154 ×10⁹/L; Creatinine 108 µmol/L; Calcium 2.31 mmol/L; Albumin 35 g/L; Total Protein 4.9 g/dL; Glucose 5.2 mmol/L.
- Day 354 (ECOG 2): M Protein 1 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.3 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.24 mg/dL; Immunoglobulin G 3.01 g/L; Immunoglobulin A 0.07 g/L; Immunoglobulin M 0.09 g/L; Lactate Dehydrogenase 2.9 µkat/L; Hemoglobin 7.63 mmol/L; Leukocytes 2.82 ×10⁹/L; Absolute Neutrophil 1.48 ×10⁹/L; Platelets 124 ×10⁹/L; Creatinine 95 µmol/L; Calcium 2.32 mmol/L; Albumin 38 g/L; Total Protein 5.3 g/dL; Glucose 4.4 mmol/L.
- Day 464 (ECOG 2): M Protein 1.9 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.3 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.24 mg/dL; Immunoglobulin G 3.52 g/L; Immunoglobulin A 0.1 g/L; Immunoglobulin M 0.1 g/L; Beta 2 Microglobulin 2.8 µg/mL; Lactate Dehydrogenase 2.7 µkat/L; Hemoglobin 8.49 mmol/L; Leukocytes 3.9 ×10⁹/L; Absolute Neutrophil 2.37 ×10⁹/L; Platelets 127 ×10⁹/L; Creatinine 117 µmol/L; Calcium 2.39 mmol/L; Albumin 38 g/L; Total Protein 5.3 g/dL; Glucose 4.6 mmol/L.
- Day 520 (ECOG 1): M Protein 2 g/dL; Immunoglobulin G 4.46 g/L; Immunoglobulin A 0.14 g/L; Immunoglobulin M 0.15 g/L; Lactate Dehydrogenase 2.48 µkat/L; Hemoglobin 8.49 mmol/L; Leukocytes 3.19 ×10⁹/L; Absolute Neutrophil 1.73 ×10⁹/L; Platelets 163 ×10⁹/L; Creatinine 101 µmol/L; Calcium 2.37 mmol/L; Albumin 38 g/L; Total Protein 5.5 g/dL; Glucose 5.1 mmol/L.
- Day 639 (ECOG 1): M Protein 3.3 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.96 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.63 mg/dL; Immunoglobulin G 7.59 g/L; Immunoglobulin A 0.39 g/L; Immunoglobulin M 0.21 g/L; Beta 2 Microglobulin 3.1 µg/mL; Lactate Dehydrogenase 2.88 µkat/L; Hemoglobin 8.62 mmol/L; Leukocytes 3.5 ×10⁹/L; Absolute Neutrophil 1.76 ×10⁹/L; Platelets 168 ×10⁹/L; Creatinine 96 µmol/L; Calcium 2.47 mmol/L; Albumin 40 g/L; Total Protein 6.3 g/dL; Glucose 5.9 mmol/L.
- Day 760 (ECOG 1): M Protein 6.6 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.3 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.79 mg/dL; Immunoglobulin G 9.58 g/L; Immunoglobulin A 0.26 g/L; Immunoglobulin M 0.23 g/L; Lactate Dehydrogenase 2.83 µkat/L; Hemoglobin 8.18 mmol/L; Leukocytes 4 ×10⁹/L; Absolute Neutrophil 2.29 ×10⁹/L; Platelets 156 ×10⁹/L; Creatinine 100 µmol/L; Calcium 2.28 mmol/L; Albumin 38 g/L; Total Protein 5.9 g/dL; Glucose 4.3 mmol/L.
- Day 814 (ECOG 1): M Protein 1.16 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 2.14 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.61 mg/dL; Immunoglobulin G 14.3 g/L; Immunoglobulin A 0.25 g/L; Immunoglobulin M 0.25 g/L; Beta 2 Microglobulin 3.2 µg/mL; Lactate Dehydrogenase 2.6 µkat/L; Hemoglobin 7.81 mmol/L; Leukocytes 4.1 ×10⁹/L; Absolute Neutrophil 2.38 ×10⁹/L; Platelets 187 ×10⁹/L; Creatinine 87 µmol/L; Calcium 2.32 mmol/L; Albumin 37 g/L; Total Protein 6.3 g/dL; Glucose 4.4 mmol/L.
- Day 926 (ECOG 1): M Protein 1.31 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 2.9 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.98 mg/dL; Immunoglobulin G 16.4 g/L; Immunoglobulin A 0.18 g/L; Immunoglobulin M 0.22 g/L; Lactate Dehydrogenase 2.65 µkat/L; Hemoglobin 8.56 mmol/L; Leukocytes 3.3 ×10⁹/L; Absolute Neutrophil 1.57 ×10⁹/L; Platelets 160 ×10⁹/L; Creatinine 98 µmol/L; Calcium 2.36 mmol/L; Albumin 38 g/L; Total Protein 6.7 g/dL; Glucose 4.5 mmol/L.
- Day 1,009 (ECOG 1): M Protein 1.59 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 4.79 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.24 mg/dL; Immunoglobulin G 19.6 g/L; Immunoglobulin A 0.15 g/L; Immunoglobulin M 0.22 g/L; Lactate Dehydrogenase 2.75 µkat/L; Hemoglobin 8 mmol/L; Leukocytes 4 ×10⁹/L; Absolute Neutrophil 2.43 ×10⁹/L; Platelets 193 ×10⁹/L; Creatinine 96 µmol/L; Calcium 2.31 mmol/L; Albumin 38 g/L; Total Protein 6.9 g/dL; Glucose 4.2 mmol/L.
- Day 1,053 (ECOG 1): M Protein 1.64 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 5.66 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.61 mg/dL; Immunoglobulin G 18.5 g/L; Immunoglobulin A 0.12 g/L; Immunoglobulin M 0.2 g/L; Lactate Dehydrogenase 2.55 µkat/L; Hemoglobin 8.18 mmol/L; Leukocytes 3.4 ×10⁹/L; Absolute Neutrophil 1.83 ×10⁹/L; Platelets 155 ×10⁹/L; Creatinine 101 µmol/L; Calcium 2.29 mmol/L; Albumin 36 g/L; Total Protein 6.6 g/dL; Glucose 4.2 mmol/L.

Other clinical attributes
- Day -5: Weight: 80 kg; Height: 180 cm.

Family history
- Relative with cancer history: yes; Relationship type: Sibling; Relationship primary diagnosis: Breast Cancer.
- Relative with cancer history: yes; Relationship type: Mother; Relationship sex at birth: female.

Biospecimens (3 samples)
- Sample MMRF_1972_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS; Days to sample procurement: -5 days.
- Sample MMRF_1972_1_PB_Whole: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS; Days to sample procurement: -5 days.
- Sample MMRF_1972_2_BM_CD138pos: Sample type: Recurrent Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Recurrence; Specimen type: Bone Marrow NOS; Days to sample procurement: 814 days (2.2 years).
